Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6927, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6927-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 3

Date:

Examination: Histopathological examination

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Total organ resection – specimen from the colon.**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the transverse colon.**

Examination performed on:

Macroscopic description:

A 12 cm length of the large intestine with periintestinal fat tissue sized 12.5 x 4.5 x 5 cm. Ulcerous tumour sized 6.0 x 4 x 1.6 found in the mucosa. The lesion surrounds 100% of the intestine circumference and narrows its lumen, is located 3 cm from one of the incision lines and 3.6 cm from the opposite one. Minimum side margin is 1.3 cm.

Microscopic description:

Adenocarcinoma tubulare (G2).

Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae pericolicae.

Incision lines clear of neoplastic lesions.

Lymphonodulitis reactiva No XVI.

Histopathological diagnosis:

Adenocarcinoma tubulare coli. Tubular adenocarcinoma of the colon.

(G2, Dukes B, Astler-Coller B2, pT3, pNO).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 6b87964f-e950-4329-b4e1-6671706ccafd (TCGA-D5-6927.C667B580-1814-4EF9-9B00-6803E665A94C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).